MMRF case MMRF_1625 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3bfb8a82-4b5f-49b6-bb27-5b756b1f3eed

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Dead; Days to death: 347 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.7 years (18,870 days); ISS stage: III; Days to last known disease status: 347 days; Days to last follow up: 347 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 12 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 32 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Doxorubicin + Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 30 days; Days to treatment end: 34 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 111 days; Days to treatment end: 111 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 243 days; Days to treatment end: 246 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 245 days; Days to treatment end: 245 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 247 days; Days to treatment end: 247 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 347.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 2): M Protein 7.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.105 mg/dL; Immunoglobulin G 104 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 15.4 µg/mL; Hemoglobin 4.53 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.39 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.73 mmol/L; Albumin 25 g/L; Total Protein 12.1 g/dL; Glucose 5.5 mmol/L; C-Reactive Protein 1 mg/dL.
- Day 83 (ECOG 1): M Protein 4.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 61.6 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 4.82 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 1.95 mmol/L; Albumin 35 g/L; Total Protein 9 g/dL; Glucose 5.78 mmol/L.
- Day 173 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 32.5 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.57 µg/mL; Lactate Dehydrogenase 7.57 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.05 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL; Glucose 6.11 mmol/L.
- Day 261 (ECOG 1): M Protein 4.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.605 mg/dL; Immunoglobulin G 49.2 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 4.51 µg/mL; Lactate Dehydrogenase 6.27 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 1.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 31 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.03 mmol/L; Albumin 33 g/L; Total Protein 7.4 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day 0: Weight: 83 kg; Height: 193 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1625_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1625_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
